Somatic mutation profile of tumor specimen 4798bb9d-7100-43aa-b615-85897d (aliquot 4798bb9d-7100-43aa-b615-85897d_D6_1) from CPTAC case 11BR006, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.5 years (19,892 days).
Specimen 4798bb9d-7100-43aa-b615-85897d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a96bc40-84c7-4b9f-8c8c-a8a19df28419.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f2cf56e9-6d6d-4e29-8222-212720 (Blood Derived Normal), aliquot f2cf56e9-6d6d-4e29-8222-212720_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9ba6eaa-4d5d-4e58-8d1a-6eb032c02d27

The open-access MAF lists 118 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 23, Intron 10, Nonsense Mutation 5, 3'UTR 4, 5'UTR 2, In Frame Del 2, Frame Shift Del 2, Splice Site 1, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.4676G>A p.R1559Q | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as rs373611754; called by muse, mutect2, varscan2
- ATF1 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50394829; called by muse, mutect2
- CIB3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs547459427, COSV54165558; called by muse, mutect2, varscan2
- CLEC3A | c.197C>T p.A66V (on ENST00000651443; = p.A57V on NM_005752.6) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as rs780701019; called by muse, mutect2, varscan2
- FOXD4L5 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.333); catalogued as COSV101073248; called by mutect2, varscan2
- GABRB1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs751931636, COSV54974645; called by muse, mutect2
- GALNT12 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777425926, COSV100899124; called by muse, mutect2, varscan2
- H4C2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1296621230, COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2, varscan2
- HAUS1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1485677159; called by muse, mutect2, varscan2
- KCNH4 | c.2438C>A p.P813H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV52919988; called by mutect2, varscan2
- KRT222 | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 161/471 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148476018, COSV67497913; called by muse, mutect2, varscan2
- LAP3 | c.1515G>C p.R505S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375901782; called by muse, mutect2, varscan2
- OR52B4 | c.509T>C p.F170S | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1031212715; called by muse, mutect2
- PRKDC | c.1896G>C p.E632D | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV58059928; called by muse, mutect2, varscan2
- RHOJ | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57458404; called by muse, mutect2
- RPLP2 | c.276G>C p.E92D | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV100337028; called by muse, mutect2, varscan2
- RUNX2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 59/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as CM104829; called by muse, mutect2, varscan2
- SEZ6L | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1416661263, COSV50659267, COSV99030704; called by muse, mutect2, varscan2
- SPEG | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679755; called by muse, mutect2, varscan2
- ZNF423 | c.2669C>A p.S890* (on ENST00000563137 / NM_001379286.1; = p.S882* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as rs777639594, COSV52186306; called by muse, mutect2, varscan2
- A2M | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA2 | c.4509G>A p.M1503I (on ENST00000614293; = p.M1473I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ABCA2 | c.4203_4229delinsTGC p.S1402_G1410delinsA (on ENST00000614293; = p.S1372_G1380delinsA on NM_001606.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 22/165 reads (13%) | called by pindel, varscan2*
- AGTPBP1 | c.1801G>A p.D601N (on ENST00000357081 / NM_001330701.2; = p.D561N on NM_015239.2) | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2
- AHDC1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ALPK2 | c.5341A>G p.R1781G | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD29 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP25 | c.1159G>A p.E387K (on ENST00000409202 / NM_001007231.3; = p.E379K on NM_014882.3) | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BRD9 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CCDC151 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CD209 | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- CHRAC1 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CYP1A2 | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.348); called by muse, mutect2
- DDX52 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- DNAH3 | c.4967T>A p.L1656* | Nonsense Mutation (SNP) | VAF 43/206 reads (21%) | called by muse, mutect2, varscan2
- DSG3 | c.1846del p.L616Wfs*24 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, varscan2
- DSG3 | c.1847T>G p.L616R | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- ENPP7 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM98A | c.972G>C p.K324N | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT2 | c.10364C>G p.S3455C | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FGL1 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FOXD2 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNTL6 | c.1516A>G p.I506V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRM1 | c.732C>G p.F244L | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- GTF3C3 | c.2562C>G p.D854E | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HAUS1 | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- HECTD2 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HYAL4 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 24/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNMB1 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF21B | c.1333A>C p.I445L | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KIF3A | c.1926_1926+6del p.X642_splice | Splice Site (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- KLF9 | c.226A>C p.I76L | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LENG8 | c.2504A>C p.H835P | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LPP | c.7C>A p.H3N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- MUC16 | c.28894G>T p.A9632S | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NCOA5 | c.367A>T p.R123* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- OSM | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHA6 | c.2168G>A p.C723Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PDLIM7 | c.1055T>A p.I352N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PEDS1 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by mutect2, varscan2
- POLG | c.3107C>A p.S1036* | Nonsense Mutation (SNP) | VAF 83/441 reads (19%) | called by muse, mutect2, varscan2
- PSMB3 | c.229A>C p.K77Q | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.332); called by muse, mutect2
- RAC3 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); called by muse, mutect2
- RXRA | c.888C>G p.D296E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SIGLEC10 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.174); called by muse, mutect2
- SMTNL1 | c.621+7G>C | Splice Region (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- SP7 | c.785del p.G262Afs*17 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- SPATC1 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SPIN4 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.946); called by muse, mutect2
- STAB2 | c.7274G>T p.R2425I | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by mutect2, varscan2
- TBC1D9B | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- TBX19 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET1 | c.5198C>A p.A1733D | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TLN2 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TRPA1 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 103/632 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- VAV2 | c.2407C>G p.Q803E | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF526 | c.1871_1876del p.M624_C625del | In Frame Del (DEL) | VAF 58/219 reads (26%) | called by mutect2, pindel, varscan2
- ACTR3 | c.829T>C p.L277= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.564C>T p.S188= | Silent (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2
- CD101 | c.2166C>T p.A722= | Silent (SNP) | VAF 36/278 reads (13%) | catalogued as rs377099186; called by muse, mutect2, varscan2
- CPS1 | c.2199A>G p.P733= | Silent (SNP) | VAF 99/413 reads (24%) | catalogued as rs780079490, COSV51803421; called by muse, mutect2, varscan2
- CSPG4 | c.414C>A p.A138= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1470058324; called by muse, mutect2, varscan2
- DRP2 | c.2709C>A p.P903= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- GALNT12 | c.336A>T p.S112= | Silent (SNP) | VAF 39/221 reads (18%) | called by muse, mutect2, varscan2
- ICMT | c.595C>T p.L199= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV59474297, COSV59474574; called by muse, mutect2, varscan2
- KDM5C | c.3249G>A p.E1083= | Silent (SNP) | VAF 64/283 reads (23%) | called by muse, mutect2, varscan2
- KIAA1109 | c.615C>T p.V205= | Silent (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- LAMP3 | c.489T>C p.S163= | Silent (SNP) | VAF 17/72 reads (24%) | called by mutect2, varscan2
- LONRF3 | c.18C>T p.I6= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs1040601935; called by muse, mutect2, varscan2
- LRIF1 | c.2160C>T p.F720= | Silent (SNP) | VAF 52/350 reads (15%) | called by muse, mutect2, varscan2
- MUC2 | c.951C>T p.I317= | Silent (SNP) | VAF 59/265 reads (22%) | called by muse, mutect2, varscan2
- OR2L13 | c.303C>T p.F101= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- PCDH12 | c.505C>T p.L169= | Silent (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- PHF3 | c.3604C>T p.L1202= | Silent (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- RPP38 | c.39C>T p.L13= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs574083337; called by muse, mutect2, varscan2
- SRRM2 | c.2286C>G p.L762= | Silent (SNP) | VAF 55/281 reads (20%) | catalogued as rs758899562, COSV57069142; called by muse, mutect2, varscan2
- TG | c.3864G>A p.Q1288= | Silent (SNP) | VAF 53/452 reads (12%) | called by muse, mutect2, varscan2
- TMEM131 | c.4239G>T p.L1413= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- TMEM159 | c.69G>T p.L23= | Silent (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- U2AF2 | c.453C>G p.L151= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- CBX2 | c.288+254G>C | Intron (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- COL25A1 | c.-1G>A | 5'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- CTBP1 | c.195+215G>C | Intron (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- FEZ1 | c.-46+552G>C | Intron (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- HSPG2 | c.3888+11A>G | Intron (SNP) | VAF 16/218 reads (7%) | catalogued as rs757452257; called by muse, mutect2
- KLF6 | c.*1785A>G | 3'UTR (SNP) | VAF 60/172 reads (35%) | called by muse, mutect2, varscan2
- LINC01169 | n.358G>A | RNA (SNP) | VAF 27/96 reads (28%) | catalogued as rs1181934273; called by muse, mutect2, varscan2
- MYH7 | c.*18C>G | 3'UTR (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- NCL | c.-48_-1del | 5'UTR (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel
- PDE4C | c.-209-23T>C | Intron (SNP) | VAF 13/94 reads (14%) | catalogued as rs1198126049; called by mutect2, varscan2
- RNF135 | c.*18C>A | 3'UTR (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- RPL9 | c.47-11C>T | Intron (SNP) | VAF 78/363 reads (21%) | catalogued as rs754417283; called by muse, mutect2, varscan2
- SLC27A1 | c.1206+130G>T | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1217+71C>G | Intron (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- SMAP1 | c.1270-807G>T | Intron (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- SORBS2 | c.-46+1247C>T | Intron (SNP) | VAF 46/283 reads (16%) | called by muse, mutect2, varscan2
- TIMM50 | chr19:39480669 C>T | 5'Flank (SNP) | VAF 43/209 reads (21%) | catalogued as rs765566612; called by muse, mutect2, varscan2
- ZNF410 | c.*460G>A | 3'UTR (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
